Surgical pathology report (de-identified scan), TCGA case TCGA-62-A46Y, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A46Y-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, lower lobe: 12.0 x 13.0 x 4.0 cm

tumor: 3.5 x 3.1 x 2.9 cm

Diagnosis:

Adenocarcinoma, mixed subtype (predominantly papillary, micropapillary, partially solid)

Infiltration of pleura visceralis

pT2, pN2 (37/39), pMx, G3

ICD-O-3

adenocarcinoma, with mixed subtypes

8255/3

Site: lung, lower lobe C34.3

hw
9/24/12

Pathologist:

Source: NCI Genomic Data Commons file e15d191d-2906-4ffc-832c-f1f373515a17 (TCGA-62-A46Y.284FE692-BC27-4E0E-A92A-2DF64FF33405.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).